MMRF case MMRF_2149 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7e828008-fa5c-45a7-80eb-910c4f5373a2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 454 days (1.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,061 days); ISS stage: II; Days to last known disease status: 454 days (1.2 years); Days to last follow up: 454 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 163 days.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 239, day 454.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 23 (ECOG 1): M Protein 3.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.399 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.6 mg/dL; Immunoglobulin G 39.1 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 5.33 µg/mL; Hemoglobin 5.52 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.7 mmol/L; Albumin 34 g/L; Total Protein 8.4 g/dL; Glucose 5.61 mmol/L.
- Day 128 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.427 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.713 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 5.6 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 13 ×10⁹/L; Absolute Neutrophil 11.7 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 10.2 mmol/L.
- Day 163 (ECOG 2): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.582 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 6.05 mmol/L.
- Day 351 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 4.14 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day 23: Weight: 71 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_2149_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 23 days.
- Sample MMRF_2149_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 23 days.
